Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1BE, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1BE-01B (Primary Tumor).

100-0-3

Carcinoma, Squamous cell, non-keratinizing, NOS
Site Code: Cervix, NOS C53.9 8072/3

12/29/10
L

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: F
DOB: [REDACTED]

Service: Gynecology
Location: [REDACTED]
MRN: [REDACTED]
Hospital #: [REDACTED]
Patient Type: [REDACTED]

Accession #: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

Physician(s): [REDACTED]

DIAGNOSIS:

UTERUS, CERVIX, RADICAL HYSTERECTOMY

- MODERATELY DIFFERENTIATED NON-KERATINIZING SQUAMOUS CELL CARCINOMA, 5 CM IN GREATEST DIMENSION
- SQUAMOUS CELL CARCINOMA INVADES TO A DEPTH OF 14 MM (TOTAL WALL THICKNESS 15 MM)
- SQUAMOUS CELL CARCINOMA IS PRESENT LESS THAN 1 MM FROM THE INKED MARGIN IN THE ANTERIOR LOWER UTERINE SEGMENT
- EXTENSIVE LYMPHATIC AND VASCULAR SPACE INVASION IS IDENTIFIED

PARAMETRIA, RADICAL HYSTERECTOMY

- NO CARCINOMA IDENTIFIED
- FOCAL ENDOSALPINGIOSIS
- VESSELS WITH COMPLEX ATHEROSCLEROSIS

LYMPH NODES, PARAMETRIAL SOFT TISSUE, RADICAL HISTERECTOMY

- NO CARCINOMA IDENTIFIED IN THREE LYMPH NODES (0/3)

VAGINA, RADICAL HYSTERECTOMY

- NO CARCINOMA OR DYSPLASIA IDENTIFIED

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- IN SITU AND INVASIVE SQUAMOUS CELL CARCINOMA EXTENSIVELY INVOLVING ENDOMETRIUM
- ENDOMETRIAL POLYPS, WITH INVOLVEMENT BY SQUAMOUS CELL CARCINOMA IN SITU
- INACTIVE ENDOMETRIUM

UTERUS, MYOMETRIUM, RADICAL HYSTERECTOMY

- LEIOMYOMATA, LARGEST 0.9 CM
- SQUAMOUS CELL CARCINOMA BY DIRECT EXTENSION

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

Source: NCI Genomic Data Commons file 5a33ab56-14d4-410e-ac16-3dc77ae20090 (TCGA-C5-A1BE.0A21AE44-27DF-4F41-BAB5-209A25087C0A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).